Somatic mutation profile of tumor specimen TCGA-BP-5176-01A (aliquot TCGA-BP-5176-01A-01D-1429-08) from TCGA case TCGA-BP-5176, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 78.7 years (28,727 days).
Specimen TCGA-BP-5176-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15136f32-25f8-48c4-9f4a-862b2e127433.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5176-11A (Solid Tissue Normal), aliquot TCGA-BP-5176-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4546b972-3c37-4df2-a825-55f3971f61a2

The open-access MAF lists 124 somatic variants for this specimen: 98 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 24, Frame Shift Del 14, Nonsense Mutation 6, Frame Shift Ins 3, In Frame Del 2, Splice Site 2, Intron 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.4375G>C p.A1459P | Missense Mutation (SNP) | VAF 47/212 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV63869424, COSV63873215; called by muse, mutect2, varscan2
- ABCB6 | c.2283T>G p.N761K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV54694175; called by muse, mutect2, varscan2
- ACTC1 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV51757889; called by muse, mutect2, varscan2
- ADAM2 | c.1440T>G p.N480K | Missense Mutation (SNP) | VAF 86/282 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.145); catalogued as COSV55860145; called by muse, mutect2, varscan2
- ADGRF2 | c.1724C>T p.A575V (on ENST00000296862 / NM_001368115.2; = p.A507V on NM_153839.7) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57287305; called by muse, mutect2, varscan2
- AKAP11 | c.5537A>T p.H1846L | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV50294136; called by muse, mutect2, varscan2
- ALPK2 | c.3151T>C p.F1051L | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64491392; called by muse, mutect2, varscan2
- AOC1 | c.2062C>G p.P688A | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.764); catalogued as COSV100711071, COSV62867590; called by muse, mutect2, varscan2
- BAZ2B | c.2560C>A p.Q854K | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV58597522; called by muse, mutect2, varscan2
- BTNL9 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV59794679; called by muse, mutect2, varscan2
- BTNL9 | c.941C>G p.A314G | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV59794708; called by muse, mutect2, varscan2
- CD19 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 14/81 reads (17%) | catalogued as COSV61188101; called by muse, mutect2, varscan2
- CDS2 | c.60G>T p.E20D | Missense Mutation (SNP) | VAF 96/373 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV66895858; called by muse, mutect2, varscan2
- CDV3 | c.730T>C p.Y244H | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs1462571075, COSV53911712; called by muse, mutect2, varscan2
- CUBN | c.5754T>G p.I1918M | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV64710889; called by muse, mutect2, varscan2
- CXorf58 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 9/280 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as COSV64858032; called by muse, mutect2
- DMAC2L | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV55413065; called by muse, mutect2, varscan2
- DMD | c.7357G>C p.E2453Q | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.452); catalogued as COSV58899085; called by muse, mutect2, varscan2
- DNAJB1 | c.380T>G p.I127S | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV54316637; called by muse, mutect2, varscan2
- EBF2 | c.970C>G p.Q324E | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as COSV68776757; called by muse, mutect2, varscan2
- ETNK1 | c.521T>A p.I174N | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV56884372; called by muse, mutect2, varscan2
- FAT2 | c.11096T>A p.L3699Q | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55815851; called by muse, varscan2
- GABPA | c.1294C>A p.H432N | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.084); catalogued as COSV61395761, COSV61397371; called by muse, mutect2, varscan2
- GOT1 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | catalogued as COSV65146987, COSV65147187; called by muse, mutect2, varscan2
- HERC1 | c.10319A>C p.K3440T | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV71246786; called by muse, mutect2
- HERPUD1 | c.899T>C p.M300T | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV55861712; called by muse, mutect2, varscan2
- HGF | c.1331A>C p.D444A | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55946831, COSV55947457; called by muse, mutect2, varscan2
- IFNA21 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 131/548 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV66518247; called by muse, mutect2, varscan2
- IL15 | c.320T>G p.I107S | Missense Mutation (SNP) | VAF 79/258 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV56724693; called by muse, mutect2, varscan2
- INO80 | c.1448C>A p.A483E | Missense Mutation (SNP) | VAF 83/288 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.118); catalogued as COSV62736990; called by muse, mutect2, varscan2
- KCNAB1 | c.1139A>T p.E380V (on ENST00000490337 / NM_172160.3; = p.E369V on NM_003471.3) | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV56743024; called by muse, mutect2, varscan2
- KCND2 | c.275T>C p.F92S | Missense Mutation (SNP) | VAF 88/344 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58573568; called by muse, varscan2
- LRP1 | c.8620C>A p.R2874S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV54505464; called by muse, mutect2, varscan2
- MCMDC2 | c.484T>A p.F162I | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58034547; called by muse, mutect2, varscan2
- NCAPD3 | c.3737A>G p.K1246R | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV73187773; called by muse, mutect2, varscan2
- NF1 | c.7783A>G p.K2595E (on ENST00000358273 / NM_001042492.3; = p.K2574E on NM_000267.3) | Missense Mutation (SNP) | VAF 105/394 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.931); catalogued as CM143480, COSV100648501, COSV62197108; called by muse, mutect2, varscan2
- NLGN4X | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV99323677; called by muse, mutect2, varscan2
- NOMO1 | c.1895-2A>G p.X632_splice | Splice Site (SNP) | VAF 44/203 reads (22%) | catalogued as COSV99814520; called by mutect2, varscan2
- NOS1 | c.3547A>C p.S1183R | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57608960; called by muse, mutect2, varscan2
- NPAS4 | c.827T>G p.I276S | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV60649480; called by muse, mutect2, varscan2
- NSUN6 | c.823dup p.I275Nfs*19 | Frame Shift Ins (INS) | VAF 36/143 reads (25%) | catalogued as rs773742633; called by mutect2, pindel, varscan2
- OR8B12 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as COSV60911344; called by muse, mutect2, varscan2
- OTX1 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56994172; called by muse, mutect2, varscan2
- PARP8 | c.1897C>G p.Q633E | Missense Mutation (SNP) | VAF 6/177 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV55857667; called by muse, mutect2
- PCED1B | c.887C>A p.S296Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.086); catalogued as COSV71395011, COSV71395060; called by muse, mutect2, varscan2
- PCNX2 | c.3403G>T p.A1135S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV50787271; called by muse, mutect2, varscan2
- PER3 | c.1997C>A p.S666* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as COSV62704919; called by muse, varscan2
- PEX2 | c.351A>T p.E117D | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.498); catalogued as COSV63813287; called by muse, mutect2, varscan2
- PGAP4 | c.1118A>T p.K373M | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); catalogued as COSV66387336; called by muse, mutect2, varscan2
- PM20D2 | c.30A>C p.E10D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV51530080; called by muse, mutect2
- PPP1R13B | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV52449976; called by muse, mutect2, varscan2
- PPP1R3D | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs1420305509, COSV62564044; called by muse, mutect2, varscan2
- PRAMEF20 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV57080667; called by muse, mutect2, varscan2
- PRMT5 | c.1223A>T p.E408V | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.178); catalogued as COSV53545236; called by muse, mutect2, varscan2
- PSG8 | c.1085C>G p.A362G | Missense Mutation (SNP) | VAF 18/524 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV60610475; called by muse, mutect2
- RAB43 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs764997936, COSV59348779; called by muse, mutect2, varscan2
- RASGEF1B | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV52336214; called by muse, mutect2, varscan2
- RNF10 | c.2290T>C p.S764P | Missense Mutation (SNP) | VAF 130/390 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58044141; called by muse, varscan2
- RNF103 | c.1343A>T p.N448I | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52894148; called by muse, mutect2, varscan2
- RUBCN | c.1980G>A p.K660= | Splice Region (SNP) | VAF 16/103 reads (16%) | catalogued as COSV56363907; called by muse, mutect2, varscan2
- SCARB2 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs752295374, COSV53668122; called by muse, mutect2, varscan2
- SIPA1L2 | c.110A>T p.K37I | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV53385865; called by muse, mutect2, varscan2
- SLC12A5 | c.2873A>T p.D958V (on ENST00000454036 / NM_001134771.2; = p.D935V on NM_020708.5) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.215); catalogued as COSV51643346; called by muse, mutect2, varscan2
- SLC47A2 | c.1589-2A>G p.X530_splice | Splice Site (SNP) | VAF 8/12 reads (67%) | catalogued as rs1003261384, COSV51566074; called by muse, varscan2
- SLCO4C1 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | catalogued as COSV60513857, COSV60515972; called by muse, mutect2, varscan2
- SMAD2 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV50994272; called by muse, mutect2, varscan2
- SOCS6 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as rs779619824, COSV67546124; called by muse, mutect2, varscan2
- SP100 | c.2655T>G p.I885M | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV60842722; called by muse, mutect2, varscan2
- SPOCK1 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756110717, COSV56441284; called by muse, mutect2, varscan2
- SYDE1 | c.1983_2003del p.P664_L670del | In Frame Del (DEL) | VAF 35/178 reads (20%) | catalogued as rs757780341; called by mutect2, varscan2
- TBC1D8B | c.2582C>G p.S861* | Nonsense Mutation (SNP) | VAF 62/308 reads (20%) | catalogued as COSV52177074; called by muse, mutect2, varscan2
- TENM1 | c.209del p.S70Lfs*32 | Frame Shift Del (DEL) | VAF 87/360 reads (24%) | catalogued as COSV100950277; called by mutect2, pindel, varscan2
- TMEM92 | c.280T>A p.C94S | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV55946110; called by muse, mutect2, varscan2
- TULP1 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775334320, CM1412147, COSV57692213; called by muse, mutect2
- UNC13B | c.3166G>C p.G1056R | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as COSV65932633, COSV65934011; called by muse, mutect2, varscan2
- USP7 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61213554; called by muse, mutect2, varscan2
- VHL | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as CD983007, COSV56546200, COSV56564223, COSV56566424, COSV56567674; called by muse, mutect2, varscan2
- ZNF354C | c.1172G>A p.R391K | Missense Mutation (SNP) | VAF 99/343 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as COSV59607687; called by muse, mutect2, varscan2
- ZNF407 | c.3469A>C p.N1157H | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1192031257, COSV55247064; called by muse, mutect2, varscan2
- ZNF423 | c.3775G>T p.V1259L (on ENST00000563137 / NM_001379286.1; = p.V1251L on NM_015069.4) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.172); catalogued as COSV52181872, COSV99284533; called by muse, mutect2, varscan2
- ZNF703 | c.1638C>A p.H546Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV58998361; called by muse, mutect2
- ZNF862 | c.2786T>C p.I929T | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs752297627, COSV56223289; called by muse, mutect2, varscan2
- ASIC5 | c.39del p.N13Kfs*4 | Frame Shift Del (DEL) | VAF 34/172 reads (20%) | called by mutect2, pindel*, varscan2
- CDC42BPB | c.3322_3323del p.T1108Gfs*15 | Frame Shift Del (DEL) | VAF 31/172 reads (18%) | called by mutect2, pindel, varscan2
- CNOT8 | c.768_781del p.C256Wfs*12 | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | called by mutect2, pindel, varscan2
- CWC27 | c.1368_1370del p.R458del | In Frame Del (DEL) | VAF 16/132 reads (12%) | called by pindel, varscan2
- DIPK1C | c.982del p.S328Qfs*15 | Frame Shift Del (DEL) | VAF 41/189 reads (22%) | called by mutect2, pindel, varscan2
- DNAH3 | c.6894del p.K2298Nfs*18 | Frame Shift Del (DEL) | VAF 44/171 reads (26%) | called by mutect2, pindel, varscan2
- FAM114A1 | c.1022_1027delinsCA p.I341Tfs*6 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | called by pindel, varscan2*
- GTF3C2 | c.2512del p.H838Ifs*98 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.6882_6883insTATA p.T2295Yfs*19 | Frame Shift Ins (INS) | VAF 43/193 reads (22%) | called by mutect2, pindel, varscan2
- PBRM1 | c.848_855del p.K283Rfs*3 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel
- PRDM2 | c.4645del p.S1549Hfs*15 | Frame Shift Del (DEL) | VAF 36/168 reads (21%) | called by mutect2, pindel, varscan2
- RALGAPA1 | c.5199dup p.E1734Rfs*4 | Frame Shift Ins (INS) | VAF 35/164 reads (21%) | called by mutect2, pindel, varscan2
- SFI1 | c.333del p.A112Pfs*45 | Frame Shift Del (DEL) | VAF 39/192 reads (20%) | called by mutect2, pindel, varscan2
- SLTM | c.425_426del p.L142Sfs*11 | Frame Shift Del (DEL) | VAF 59/270 reads (22%) | called by mutect2, pindel, varscan2
- TH | c.1510del p.Q504Rfs*21 (on ENST00000381178 / NM_199292.3; = p.Q473Rfs*21 on NM_000360.4) | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- ZFR2 | c.2186del p.Q729Rfs*10 | Frame Shift Del (DEL) | VAF 39/124 reads (31%) | called by mutect2, pindel, varscan2
- ACSM1 | c.1110G>A p.S370= | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as rs766792961, COSV54634078; called by muse, mutect2, varscan2
- AKAP6 | c.5151G>C p.S1717= | Silent (SNP) | VAF 57/222 reads (26%) | catalogued as COSV55208465, COSV55231445; called by muse, mutect2, varscan2
- ANK3 | c.11262A>G p.G3754= | Silent (SNP) | VAF 92/366 reads (25%) | catalogued as COSV55049441; called by muse, mutect2, varscan2
- ARL14EP | c.405G>A p.Q135= | Silent (SNP) | VAF 35/151 reads (23%) | catalogued as COSV56342394; called by muse, mutect2, varscan2
- CABIN1 | c.1069C>T p.L357= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as COSV54079511, COSV99574032; called by muse, mutect2, varscan2
- CACNA1S | c.4776G>C p.A1592= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV62937738; called by muse, mutect2, varscan2
- DICER1 | c.5517G>T p.R1839= | Silent (SNP) | VAF 104/382 reads (27%) | catalogued as COSV58616996, COSV58626404; called by muse, mutect2, varscan2
- DLAT | c.1638C>G p.T546= | Silent (SNP) | VAF 39/183 reads (21%) | catalogued as rs1051066804, COSV54769734; called by muse, mutect2, varscan2
- FAM171B | c.750T>C p.P250= | Silent (SNP) | VAF 87/283 reads (31%) | catalogued as COSV59001745; called by muse, mutect2, varscan2
- GNAS | c.891C>T p.L297= | Silent (SNP) | VAF 42/195 reads (22%) | catalogued as rs767792339, COSV55673120; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR171 | c.354C>T p.H118= | Silent (SNP) | VAF 46/171 reads (27%) | catalogued as COSV56372900; called by muse, mutect2, varscan2
- IFNAR1 | c.813A>T p.G271= | Silent (SNP) | VAF 54/220 reads (25%) | catalogued as COSV54251289; called by muse, mutect2, varscan2
- MYOM2 | c.870G>A p.R290= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV50705340; called by muse, mutect2, varscan2
- MYOM3 | c.165A>G p.E55= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV58391715; called by muse, mutect2, varscan2
- OTX2 | c.132G>T p.T44= (on ENST00000408990 / NM_172337.3; = p.T52= on NM_021728.4) | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV59765661; called by muse, mutect2, varscan2
- PCDHGA8 | c.834A>G p.A278= | Silent (SNP) | VAF 46/169 reads (27%) | catalogued as COSV53917476; called by muse, mutect2, varscan2
- RNF169 | c.1047A>T p.L349= | Silent (SNP) | VAF 43/161 reads (27%) | catalogued as COSV55131199; called by muse, mutect2, varscan2
- RRP9 | c.465C>A p.T155= | Silent (SNP) | VAF 60/160 reads (38%) | catalogued as COSV51753544; called by muse, mutect2, varscan2
- SERAC1 | c.1038A>G p.E346= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as COSV65595983; called by muse, mutect2, varscan2
- TBL2 | c.1110G>T p.R370= | Silent (SNP) | VAF 40/183 reads (22%) | catalogued as COSV59786475; called by muse, mutect2, varscan2
- TP53I13 | c.117G>A p.E39= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1178755719, COSV56195011, COSV56195286; called by muse, mutect2
- TPCN1 | c.1854C>A p.T618= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV59233678; called by muse, mutect2
- UTRN | c.1758A>T p.T586= | Silent (SNP) | VAF 48/201 reads (24%) | catalogued as COSV62330440; called by muse, mutect2, varscan2
- VHL | c.564G>T p.L188= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV56546177; called by muse, mutect2, varscan2
- TMEM107 | c.*733G>T | 3'UTR (SNP) | VAF 48/157 reads (31%) | catalogued as rs186890613, COSV100328829; called by muse, mutect2, varscan2
- TTN | c.10360+4669del | Intron (DEL) | VAF 98/362 reads (27%) | called by mutect2, pindel, varscan2
